CCDI case PBBPLW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Peripheral nerves and autonomic nervous system.
https://portal.gdc.cancer.gov/cases/3358fd5a-1d16-4a41-8d15-e8e219867442

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Cauda equina; Age at diagnosis: 11.3 years (4,117 days).

Biospecimens (3 samples)
- Sample 0DE7CW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DE7E5: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DE7FS: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
